Somatic mutation profile of tumor specimen TCGA-A6-2678-01A (aliquot TCGA-A6-2678-01A-01D-1953-10) from TCGA case TCGA-A6-2678, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Transverse colon; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 43.9 years (16,030 days).
Specimen TCGA-A6-2678-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 93328762-3cb5-4eec-a0f6-b39cc7a9c12f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-2678-10A (Blood Derived Normal), aliquot TCGA-A6-2678-10A-01D-1953-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ad1fc0b-d12d-4b3e-b698-e2a06235b7c3

The open-access MAF lists 25 somatic variants for this specimen: 22 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 21, Silent 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMARCB1 | c.992G>A p.R331H (on ENST00000263121; = p.R377H on NM_003073.5) | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs387906812, CM122478, COSV51954090, COSV51954233, COSV51954740; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- ALPI | c.1486G>C p.A496P | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV99785805; called by muse, varscan2
- B4GALNT4 | c.446C>T p.T149M | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as rs200752314, COSV100327376; called by muse, mutect2, varscan2
- COL25A1 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs1233681099, COSV101211297; called by muse, mutect2, varscan2
- COL4A6 | c.4243C>T p.P1415S | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.67); PolyPhen benign (0.019); catalogued as COSV100563841; called by muse, mutect2, varscan2
- EFNA2 | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.213); catalogued as COSV99288949; called by muse, mutect2, varscan2
- GP6 | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 217/398 reads (55%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs373154193; called by muse, mutect2, varscan2
- HCN2 | c.1311C>A p.S437R | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); catalogued as COSV99241545, COSV99241604; called by muse, mutect2, varscan2
- HDGFL1 | c.32G>C p.S11T | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT tolerated (0.97); PolyPhen benign (0.048); catalogued as COSV100014543, COSV57751632; called by muse, mutect2, varscan2
- HYDIN | c.13981C>A p.L4661M | Missense Mutation (SNP) | VAF 54/487 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); catalogued as rs1433805596; called by muse, mutect2, varscan2
- JCAD | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.069); catalogued as rs747342925, COSV100948256; called by muse, mutect2, varscan2
- MMP17 | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 70/159 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.085); catalogued as rs368524477; called by muse, mutect2, varscan2
- MSLNL | c.727C>A p.P243T | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.129); catalogued as COSV99558132; called by muse, mutect2, varscan2
- PLSCR3 | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 78/111 reads (70%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs376916902; called by muse, mutect2, varscan2
- PTPRT | c.3199C>T p.R1067C | Missense Mutation (SNP) | VAF 66/196 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757894088, COSV100626419; called by muse, mutect2, varscan2
- RBM15B | c.1712G>A p.R571H | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV100082056; called by muse, mutect2, varscan2
- TAPBP | c.1021C>T p.Q341* | Nonsense Mutation (SNP) | VAF 10/19 reads (53%) | catalogued as COSV70457090; called by muse, mutect2, varscan2
- TMCO4 | c.689C>T p.A230V | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.185); catalogued as COSV99616239; called by muse, mutect2, varscan2
- ULK1 | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs377295019; called by muse, mutect2, varscan2
- VWA8 | c.4825G>A p.E1609K | Missense Mutation (SNP) | VAF 29/346 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.225); catalogued as rs770225079, COSV65001877; called by muse, mutect2
- ZMYM6 | c.3070C>G p.P1024A | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.914); catalogued as COSV100593105; called by muse, mutect2, varscan2
- SOX7 | c.55C>A p.L19M | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.18); PolyPhen benign (0.035); called by muse, varscan2
- ATN1 | c.3456C>G p.R1152= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV99980700; called by muse, mutect2, varscan2
- CNTNAP2 | c.18C>T p.R6= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV62265327; called by muse, mutect2, varscan2
- DIAPH1 | c.2556G>A p.L852= | Silent (SNP) | VAF 210/532 reads (39%) | catalogued as COSV99526263; called by muse, mutect2, varscan2
